Somatic mutation profile of tumor specimen BLGSP-71-08-00027-01A (aliquot BLGSP-71-08-00027-01A-01D-A663-33) from CGCI case BLGSP-71-08-00027, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: female; Vital status: Dead; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 6.1 years (2,211 days).
Specimen BLGSP-71-08-00027-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node(s) Splenic; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09e51285-29f8-4475-bcde-7a814b26d477.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BLGSP-71-08-00027-10A (Blood Derived Normal), aliquot BLGSP-71-08-00027-10A-01D-A663-33; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/252f804c-2122-461d-ac13-2aa3ee9f7c0d

The open-access MAF lists 10 somatic variants for this specimen: 4 protein-altering or splice-affecting, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Nonsense Mutation 2, Missense Mutation 2, 5'Flank 2, 5'UTR 2, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.694A>T p.I232F | Missense Mutation (SNP) | VAF 6/12 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV52677046, COSV52701937, COSV52704131, COSV53187960; called by muse, varscan2
- HLA-B | c.856C>T p.Q286* | Nonsense Mutation (SNP) | VAF 45/107 reads (42%) | catalogued as COSV69522726; called by muse, mutect2, varscan2
- LRP1B | c.12505C>A p.Q4169K | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- PCBP1 | c.474T>A p.C158* | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | called by muse, mutect2, varscan2
- MYC | chr8:127735585 C>T | 5'Flank (SNP) | VAF 110/252 reads (44%) | catalogued as COSV104388365; called by muse, varscan2
- MYC | chr8:127735586 C>T | 5'Flank (SNP) | VAF 109/252 reads (43%) | called by muse, varscan2
- MYC | c.-415T>A | 5'UTR (SNP) | VAF 5/16 reads (31%) | catalogued as rs1299642922; called by muse, mutect2, varscan2
- MYC | c.-180C>T | 5'UTR (SNP) | VAF 35/76 reads (46%) | catalogued as COSV104388036, COSV104388052, COSV104388259; called by muse, mutect2, varscan2
- PAX5 | c.47-5757G>C | Intron (SNP) | VAF 21/41 reads (51%) | catalogued as rs116815140, COSV63907662, COSV63911600; called by muse, mutect2, varscan2
- RNU4-25P | chr8:128009226 T>A | 3'Flank (SNP) | VAF 42/109 reads (39%) | called by muse, mutect2, varscan2
